MMRF case MMRF_2196 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cc3cd8c6-d59f-4998-be47-520e331a4a54

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,043 days); ISS stage: I; Days to last known disease status: 857 days (2.3 years); Days to last follow up: 857 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 406 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -45: M Protein 5.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 131 mg/dL; Immunoglobulin G 66.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.4 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.75 mmol/L; Albumin 37 g/L; Total Protein 11.5 g/dL; Glucose 14.3 mmol/L.
- Day 92 (ECOG 2): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.65 mg/dL; Immunoglobulin G 14.1 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 10.1 mmol/L.
- Day 162 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.56 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.26 µg/mL; Lactate Dehydrogenase 34.6 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 38.1 ×10⁹/L; Absolute Neutrophil 29.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 11.1 mmol/L.
- Day 249: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.61 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.77 mmol/L.
- Day 305: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.39 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.8 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 10.5 mmol/L.
- Day 381: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.69 mg/dL; Immunoglobulin G 11 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 27.2 mmol/L.
- Day 465: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.52 mg/dL; Immunoglobulin G 11.2 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 15 mmol/L.
- Day 613: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.1 mg/dL; Immunoglobulin G 13 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 13.5 mmol/L.
- Day 682: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.84 mg/dL; Immunoglobulin G 14.2 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 17.5 mmol/L.
- Day 742: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.1 mg/dL; Immunoglobulin G 13.5 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 2.8 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 21.8 mmol/L.
- Day 857: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.3 mg/dL; Immunoglobulin G 13.9 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 17.1 mmol/L.

Other clinical attributes
- Day -45: Weight: 95 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2196_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -45 days.
- Sample MMRF_2196_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -45 days.
